Somatic mutation profile of tumor specimen TARGET-30-PAUBDC-01A (aliquot TARGET-30-PAUBDC-01A-01D) from TARGET case TARGET-30-PAUBDC, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.2 years (819 days).
Specimen TARGET-30-PAUBDC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a08711b-89e4-4f28-863f-f065c1f03f51.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUBDC-10A (Blood Derived Normal), aliquot TARGET-30-PAUBDC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/818938d4-61fe-484d-a7c0-55f264c03213

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC1 | c.12031G>C p.A4011P | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71247703; called by muse, mutect2, varscan2
- PTGS2 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66569177; called by muse, mutect2, varscan2
- STAG1 | c.615C>G p.S205= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52608763, COSV52612476, COSV99364121; called by muse, mutect2, varscan2
